CPTAC case C3L-02604 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5657ec01-7e1d-4f50-9053-12919f134f14

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1932; Vital status: Dead; Days to death: 118 days; Year of death: 2017; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Tail of pancreas; Age at diagnosis: 84.9 years (31,007 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 118 days; Progression or recurrence: no; Days to last follow up: 110 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 9; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: No.

Follow-up (1 entry)
- Days to follow up: 110 days; Disease response: Progressive Disease.

Other clinical attributes
- Weight: 62 kg; Height: 160 cm; BMI: 24.22.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 29; Cigarettes per day: 20; Tobacco smoking onset year: 1952; Tobacco smoking quit year: 1981; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 29.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02604-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 215 mg; Time between excision and freezing: 30 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02604-21: Section location: Tail; Percent tumor nuclei: 75; Percent necrosis: 10.
- Sample C3L-02604-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
